Gene-level copy-number profile of tumor specimen TCGA-63-A5MT-01A from TCGA case TCGA-63-A5MT, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.08ffebbf-a98d-48ee-b571-4d9212a780b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5fcc5b7-b53c-44f5-ae70-315046b05757

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 12,836; copy number 2: 33,780; copy number 3: 8,398; copy number 4: 3,357; copy number 5: 397; copy number 6: 474; copy number 7: 84; copy number 8: 225; copy number 9: 36; copy number 10: 15; copy number 13: 14; copy number 14: 32; copy number 15: 2; copy number 25: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MT-01A-21D-A26L-01): tumor purity 0.39, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,165,552, 48 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr9:26,642,697–32,869,595, 69 genes (broad region; genes not listed).
- chr9:32,926,051–32,926,450, 1 gene: BOLA3P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,330 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–206,464,443, 91 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:209,686,178–210,676,296, 17 genes, copy number 5 (within-gene range 4–5): HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25, SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P.
- chr1:239,386,565–239,915,452, 2 genes, copy number 5 (within-gene range 3–5): CHRM3, CHRM3-AS2.
- chr2:48,529,925–51,225,575, 22 genes, copy number 6–15 (within-gene range 4–30): STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1.
- chr8:79,259,402–80,231,232, 17 genes, copy number 8: AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P.
- chr8:98,958,277–100,559,784, 36 genes, copy number 9 (within-gene range 2–9): VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62.
- chr8:126,325,454–126,329,538, 1 gene, copy number 13: AC087667.1.
- chr8:127,072,694–131,712,980, 58 genes, copy number 6–13: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1.
- chr9:32,886,601–33,025,130, 1 gene, copy number 6 (within-gene range 0–6): APTX.
- chr9:32,945,996–34,774,466, 91 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:135,546,126–138,203,325, 145 genes, copy number 5 (broad region; genes not listed).
- chr11:11,956,207–23,893,557, 211 genes, copy number 5–25 (within-gene range 1–25) (broad region; genes not listed).
- chr11:32,112,049–32,343,409, 1 gene, copy number 7 (within-gene range 3–7): THEM7P.
- chr11:32,387,775–36,232,136, 83 genes, copy number 7 (broad region; genes not listed).
- chr11:69,909,184–75,815,406, 220 genes, copy number 6–8 (broad region; genes not listed).
- chr11:75,835,215–75,942,435, 6 genes, copy number 8: Y_RNA, Y_RNA, PPP1R1AP1, AP003168.2, RNA5SP344, AP003168.1.
- chr12:459,939–6,997,428, 198 genes, copy number 6–8 (within-gene range 1–8) (broad region; genes not listed).
- chr14:22,985,894–23,792,236, 45 genes, copy number 5 (within-gene range 2–5): C14orf93, AL132780.5, PSMB5, AL132780.4, PSMB11, CDH24, ACIN1, C14orf119, LMLN2, CEBPE, SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1, JPH4, AL135999.3, DHRS2, AL160237.1, BRD7P1, AL160237.3, RN7SKP205.
- chr22:19,565,203–21,081,018, 85 genes, copy number 5–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
